Somatic mutation profile of tumor specimen TCGA-DD-AACG-01A (aliquot TCGA-DD-AACG-01A-11D-A40R-10) from TCGA case TCGA-DD-AACG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G4; Age at diagnosis: 52.5 years (19,174 days).
Specimen TCGA-DD-AACG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36d17736-d9df-4f18-8519-9f6790d5b938.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACG-10A (Blood Derived Normal), aliquot TCGA-DD-AACG-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67de2827-3ebb-4a1b-8cdf-8ffa2e8b1843

The open-access MAF lists 110 somatic variants for this specimen: 84 protein-altering or splice-affecting, 25 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 25, Nonsense Mutation 5, Frame Shift Del 4, In Frame Del 3, Splice Region 1, Frame Shift Ins 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 61/83 reads (73%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACP3 | c.1214G>C p.R405P | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV100668429, COSV63641046; called by muse, mutect2, varscan2
- ACTRT2 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); catalogued as rs756034974, COSV65758948; called by muse, mutect2, varscan2
- ADAMTS9 | c.5462C>A p.A1821D | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV99900190; called by muse, mutect2, varscan2
- AMOTL1 | c.2837T>C p.F946S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.226); catalogued as COSV100504735; called by muse, mutect2, varscan2
- APOB | c.10221G>T p.E3407D | Missense Mutation (SNP) | VAF 51/83 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.253); catalogued as COSV99268020; called by muse, mutect2, varscan2
- ARL3 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs368901451; called by muse, mutect2, varscan2
- ARMC9 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 56/86 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV63022228; called by muse, mutect2, varscan2
- ARRDC4 | c.875C>A p.S292Y | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV99164503; called by muse, mutect2, varscan2
- BRINP3 | c.380T>A p.L127H | Missense Mutation (SNP) | VAF 164/257 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100819447, COSV66537737; called by muse, mutect2, varscan2
- BRWD1 | c.6317A>G p.K2106R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.011); catalogued as COSV100314093; called by muse, mutect2, varscan2
- CBX4 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV99490564; called by muse, varscan2
- CCDC116 | c.977G>C p.G326A | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as COSV99488779, COSV99489010; called by muse, mutect2, varscan2
- CEP120 | c.51T>G p.G17= | Splice Region (SNP) | VAF 15/74 reads (20%) | catalogued as COSV100071458; called by muse, mutect2, varscan2
- CEP162 | c.2699C>A p.S900Y | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV100003387; called by muse, mutect2
- CHRM3 | c.538C>G p.R180G | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55109951, COSV99699460; called by muse, mutect2, varscan2
- CIT | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV99950976; called by muse, mutect2, varscan2
- CLEC9A | c.43C>G p.P15A | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV100872872, COSV63349582, COSV63351601; called by muse, mutect2, varscan2
- CLK2 | c.490G>T p.E164* (on ENST00000368361 / NM_001294339.2; = p.E163* on NM_003993.4) | Nonsense Mutation (SNP) | VAF 16/104 reads (15%) | catalogued as COSV100751928; called by muse, mutect2, varscan2
- COBLL1 | c.1349A>G p.H450R (on ENST00000392717; = p.H412R on NM_014900.5) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99528678; called by muse, mutect2, varscan2
- CPA4 | c.1262A>T p.Y421F | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99745352; called by muse, mutect2, varscan2
- CREB3L2 | c.1415A>T p.D472V | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV100382292; called by muse, mutect2, varscan2
- CYP2E1 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759928543, COSV53312560; called by muse, mutect2
- DARS1 | c.503A>T p.E168V | Missense Mutation (SNP) | VAF 202/332 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV99927922; called by muse, mutect2, varscan2
- DDX39B | c.256C>G p.L86V | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as COSV100795279; called by muse, mutect2, varscan2
- DHX57 | c.2750A>T p.E917V | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99769949; called by muse, mutect2, varscan2
- DIS3L | c.359A>G p.E120G (on ENST00000319212 / NM_001143688.3; = p.E37G on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100055603; called by muse, mutect2, varscan2
- DMBT1 | c.587A>G p.D196G | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100354096; called by muse, mutect2, varscan2
- DUOX2 | c.3862C>A p.Q1288K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV101199891; called by muse, mutect2, varscan2
- EPHA4 | c.1076A>G p.D359G | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99917492; called by muse, mutect2, varscan2
- FAM83G | c.1414C>A p.P472T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV100525508; called by muse, mutect2, varscan2
- GBF1 | c.5164G>C p.V1722L (on ENST00000369983 / NM_001377137.1; = p.V1721L on NM_004193.3) | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT tolerated (0.2); PolyPhen benign (0.225); catalogued as COSV100890668; called by muse, mutect2, varscan2
- GLYATL1 | c.906T>G p.F302L (on ENST00000317391 / NM_001354699.1; = p.F333L on NM_080661.4) | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV100265561; called by muse, mutect2, varscan2
- HBD | c.421G>T p.A141S | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV99496872; called by muse, mutect2, varscan2
- IQGAP3 | c.4565A>G p.D1522G | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1277547601, COSV100752367; called by muse, mutect2, varscan2
- ISLR2 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as COSV100679780; called by muse, mutect2, varscan2
- KCNT1 | c.1412A>G p.Q471R (on ENST00000488444; = p.Q490R on NM_020822.3) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs750267867, COSV99706671; called by muse, mutect2, varscan2
- KIAA2026 | c.4123C>T p.H1375Y | Missense Mutation (SNP) | VAF 43/51 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs1179501803, COSV101199203; called by muse, mutect2, varscan2
- KIR3DL2 | c.586T>C p.Y196H | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs749665656; called by muse, mutect2
- KRT13 | c.926C>A p.T309N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV99877513; called by muse, mutect2, varscan2
- LARGE1 | c.1148C>G p.S383C | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100506331, COSV100506588; called by muse, mutect2, varscan2
- MEI1 | c.3220G>A p.A1074T | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.439); catalogued as COSV100300339; called by muse, mutect2, varscan2
- MKI67 | c.1207G>C p.A403P | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); catalogued as rs1427344802, COSV100896984; called by muse, mutect2, varscan2
- MVB12B | c.340A>G p.M114V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.223); catalogued as rs1351848910, COSV100753151; called by muse, mutect2, varscan2
- N4BP2 | c.5226C>G p.I1742M | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99789275; called by muse, mutect2, varscan2
- NEXMIF | c.976A>G p.T326A | Missense Mutation (SNP) | VAF 66/77 reads (86%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV50021540; called by muse, mutect2, varscan2
- NPAP1 | c.1736A>T p.D579V | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs758609267, COSV100276176; called by muse, mutect2, varscan2
- NUDT18 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.024); catalogued as COSV99249269; called by muse, mutect2, varscan2
- PDE6A | c.2216C>A p.A739D | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99678721; called by muse, mutect2, varscan2
- PIM1 | c.481T>A p.C161S | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as COSV100998775; called by muse, mutect2, varscan2
- PLXNA3 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100860240; called by muse, mutect2, varscan2
- PLXND1 | c.4601C>G p.T1534R | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100140382; called by muse, mutect2, varscan2
- POM121L12 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.025); catalogued as rs202031574, COSV68692498; called by muse, mutect2, varscan2
- PRDM9 | c.1624C>A p.H542N | Missense Mutation (SNP) | VAF 77/294 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.176); catalogued as COSV99691244; called by muse, mutect2, varscan2
- PRR5 | c.1034C>T p.P345L (on ENST00000336985 / NM_181333.4; = p.P336L on NM_015366.4) | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.099); catalogued as rs776983827, COSV99134904; called by muse, mutect2, varscan2
- RARA | c.649C>A p.R217S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as COSV54191803, COSV54193672, COSV99565431; called by muse, mutect2, varscan2
- RESF1 | c.2831A>G p.D944G | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.656); catalogued as rs773421238, COSV100440609; called by muse, mutect2, varscan2
- SALL3 | c.3371C>A p.S1124* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as rs867553343, COSV101610056, COSV73306248; called by muse, mutect2, varscan2
- SCN11A | c.4001A>T p.N1334I | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100182548; called by muse, mutect2, varscan2
- SEL1L2 | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1323992078, COSV99533919; called by muse, mutect2, varscan2
- SIM1 | c.570G>T p.K190N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99492775; called by muse, mutect2, varscan2
- SIX5 | c.2008G>T p.E670* | Nonsense Mutation (SNP) | VAF 73/103 reads (71%) | catalogued as COSV99353676; called by muse, mutect2, varscan2
- SLC37A1 | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564499706, COSV100721835; called by muse, mutect2, varscan2
- SLC6A11 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs979049585, COSV54389422; called by muse, mutect2, varscan2
- SOX9 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 105/257 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs1433090383, COSV99818751; called by muse, mutect2, varscan2
- SPICE1 | c.416C>A p.S139Y | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99871810; called by muse, mutect2, varscan2
- SULF1 | c.1805G>A p.S602N | Missense Mutation (SNP) | VAF 117/419 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.077); catalogued as rs1012374804, COSV99484324; called by muse, mutect2, varscan2
- TFAP2B | c.733A>G p.K245E | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV99540864; called by muse, mutect2, varscan2
- TMEM267 | c.398A>G p.H133R | Missense Mutation (SNP) | VAF 104/168 reads (62%) | SIFT tolerated (0.24); PolyPhen benign (0.049); catalogued as COSV67993158; called by muse, mutect2, varscan2
- UBA1 | c.1643A>G p.H548R | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.598); catalogued as COSV100256075; called by muse, mutect2, varscan2
- VWF | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV54616485; called by muse, mutect2, varscan2
- XPO5 | c.3359A>T p.E1120V | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV99541412; called by muse, mutect2, varscan2
- ZNF282 | c.946A>G p.I316V | Missense Mutation (SNP) | VAF 122/264 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs141109561; called by muse, mutect2, varscan2
- ZNF518B | c.1580T>A p.L527* | Nonsense Mutation (SNP) | VAF 55/155 reads (35%) | catalogued as COSV100456887, COSV58721099; called by muse, mutect2, varscan2
- ZNF592 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100246122; called by muse, mutect2, varscan2
- ARID1A | c.324_328del p.P109Afs*6 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- CEP164 | c.1344_1349del p.K449_D450del | In Frame Del (DEL) | VAF 19/52 reads (37%) | called by mutect2, pindel, varscan2
- COL11A2 | c.4166dup p.G1390Rfs*35 (on ENST00000341947 / NM_080680.3; = p.G1283Rfs*35 on NM_080679.2) | Frame Shift Ins (INS) | VAF 45/123 reads (37%) | called by mutect2, pindel, varscan2
- NCBP1 | c.1600+1_1600+26del p.X534_splice | Splice Site (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- PLEKHG1 | c.3506_3507del p.K1169Rfs*5 | Frame Shift Del (DEL) | VAF 23/78 reads (29%) | called by mutect2, pindel, varscan2
- PTPMT1 | c.369del p.L124Wfs*24 | Frame Shift Del (DEL) | VAF 29/90 reads (32%) | called by mutect2, pindel, varscan2
- SCP2 | c.1379_1389del p.A460Efs*7 | Frame Shift Del (DEL) | VAF 22/129 reads (17%) | called by mutect2, pindel, varscan2
- SHB | c.215_220del p.D72_S74delinsG | In Frame Del (DEL) | VAF 29/71 reads (41%) | called by mutect2, pindel, varscan2
- ZNF317 | c.940_960del p.A314_H320del | In Frame Del (DEL) | VAF 33/43 reads (77%) | called by mutect2, pindel, varscan2
- CD44 | c.372A>T p.P124= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV99555988, COSV99556003; called by muse, mutect2, varscan2
- CLIP4 | c.876A>T p.A292= | Silent (SNP) | VAF 83/137 reads (61%) | catalogued as COSV100192429; called by muse, mutect2, varscan2
- COLQ | c.783C>A p.G261= | Silent (SNP) | VAF 58/351 reads (17%) | catalogued as rs745798750, COSV101082525; called by muse, mutect2, varscan2
- DARS2 | c.759C>T p.G253= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as rs149916824, COSV99508907; called by muse, mutect2, varscan2
- EYA1 | c.1011C>T p.H337= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as COSV58173876; called by muse, mutect2, varscan2
- KLRG2 | c.156G>C p.G52= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs1026447413, COSV100572583, COSV61800716; called by muse, mutect2, varscan2
- KRT13 | c.927C>A p.T309= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV55838969, COSV99877511; called by muse, mutect2, varscan2
- LST1 | c.58C>T p.L20= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV53000259; called by muse, mutect2, varscan2
- MAGEC1 | c.1806G>T p.G602= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as COSV99596504; called by muse, mutect2, varscan2
- MAGEC3 | c.1188C>A p.P396= | Silent (SNP) | VAF 38/43 reads (88%) | catalogued as COSV100025641; called by muse, mutect2, varscan2
- MS4A7 | c.495T>C p.Y165= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100279764; called by muse, mutect2, varscan2
- OGFR | c.1014G>T p.G338= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as COSV99284461; called by muse, mutect2, varscan2
- PDZRN4 | c.945T>C p.P315= (on ENST00000402685 / NM_001164595.2; = p.P57= on NM_013377.4) | Silent (SNP) | VAF 36/56 reads (64%) | catalogued as COSV100115443, COSV54213555; called by muse, mutect2, varscan2
- PLCXD3 | c.270T>A p.A90= | Silent (SNP) | VAF 123/209 reads (59%) | catalogued as COSV100126379; called by muse, mutect2, varscan2
- R3HDM1 | c.3165C>G p.V1055= | Silent (SNP) | VAF 43/191 reads (23%) | catalogued as rs767349366, COSV99926779; called by muse, mutect2, varscan2
- RALGDS | c.525A>G p.R175= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV100924561; called by muse, mutect2, varscan2
- SIX5 | c.2007G>T p.L669= | Silent (SNP) | VAF 72/102 reads (71%) | catalogued as COSV99353677; called by muse, mutect2, varscan2
- TMTC4 | c.903G>T p.V301= (on ENST00000376234 / NM_001350577.2; = p.V320= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV100168893; called by muse, mutect2, varscan2
- TRPM1 | c.2418C>T p.N806= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as COSV99855229; called by muse, mutect2, varscan2
- UBXN10 | c.306A>G p.Q102= | Silent (SNP) | VAF 26/145 reads (18%) | catalogued as COSV100907858; called by muse, mutect2, varscan2
- USP2 | c.447T>C p.D149= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV99489965; called by muse, mutect2, varscan2
- ZFP64 | c.453C>T p.C151= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs918177723, COSV99403022; called by muse, mutect2, varscan2
- ZNF208 | c.3075A>G p.G1025= | Silent (SNP) | VAF 46/292 reads (16%) | catalogued as rs746910347, COSV101237205; called by muse, mutect2
- ZNF502 | c.1290T>A p.T430= | Silent (SNP) | VAF 54/139 reads (39%) | catalogued as COSV99939875; called by muse, mutect2, varscan2
- ZNF778 | c.537C>T p.F179= | Silent (SNP) | VAF 48/68 reads (71%) | catalogued as rs755522644, COSV100124622; called by muse, mutect2, varscan2
- MIR514A2 | n.5T>C | RNA (SNP) | VAF 122/415 reads (29%) | called by muse, mutect2, varscan2
